Somatic mutation profile of tumor specimen 0DWYWL from CCDI case PBCPNE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.1 years (2,610 days).
Specimen 0DWYWL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) edbdb73f-baa7-47bc-92a2-b1e428e061be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWYUU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f70952d6-c2bb-4ff0-94c7-947525a229fc

The open-access MAF lists 21 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, RNA 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 274/596 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic /  other / pathogenic; called by muse, varscan2
- SMARCA4 | c.3727C>T p.R1243W | Missense Mutation (SNP) | VAF 177/378 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60786131, COSV60797427; called by muse, varscan2
- CERS5 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 55/539 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV58190080; called by muse, varscan2
- CLASRP | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 173/351 reads (49%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs766487326; called by muse, varscan2
- KAT6A | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 264/828 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1234908185; called by muse, varscan2
- KLRC1 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 370/856 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.497); catalogued as rs1415053226, COSV61724770, COSV61725066; called by muse, varscan2
- OTUD6A | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 221/443 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.382); catalogued as rs750198436, COSV100610887; called by muse, varscan2
- PCDHGA5 | c.1939G>T p.E647* | Nonsense Mutation (SNP) | VAF 109/378 reads (29%) | catalogued as COSV53898902; called by muse, varscan2
- RTL1 | c.2824G>A p.E942K | Missense Mutation (SNP) | VAF 36/346 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.267); catalogued as rs781425496, COSV66016588; called by muse, varscan2
- S1PR4 | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 152/317 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs750351396; called by muse, varscan2
- ZNF423 | c.2833C>T p.R945W (on ENST00000563137 / NM_001379286.1; = p.R937W on NM_015069.4) | Missense Mutation (SNP) | VAF 182/398 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV52193177, COSV52198294; called by muse, varscan2
- DISC1 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 40/398 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- FOXO3 | c.481T>C p.S161P | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- NUTM2F | c.2130G>T p.K710N | Missense Mutation (SNP) | VAF 193/736 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, varscan2
- ABCA10 | c.1998G>A p.T666= | Silent (SNP) | VAF 184/484 reads (38%) | catalogued as rs769826128, COSV99289370; called by muse, varscan2
- HDGFL2 | c.1071C>T p.A357= | Silent (SNP) | VAF 78/164 reads (48%) | catalogued as rs1568214734; called by muse, varscan2
- PARP15 | c.873G>A p.K291= (on ENST00000464300 / NM_001113523.3; = p.K57= on NM_152615.2) | Silent (SNP) | VAF 128/558 reads (23%) | called by muse, varscan2
- SPRED2 | c.630C>T p.D210= | Silent (SNP) | VAF 116/489 reads (24%) | catalogued as rs768532972; called by muse, varscan2
- WDR13 | c.591C>T p.I197= | Silent (SNP) | VAF 169/364 reads (46%) | called by muse, varscan2
- DCHS2 | n.458G>A | RNA (SNP) | VAF 234/542 reads (43%) | catalogued as rs1409220259; called by muse, varscan2
- SNAPC4 | c.-50G>T | 5'UTR (SNP) | VAF 106/230 reads (46%) | called by muse, varscan2
